Somatic mutation profile of tumor specimen TCGA-18-3417-01A (aliquot TCGA-18-3417-01A-01D-1441-08) from TCGA case TCGA-18-3417, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 65.8 years (24,019 days).
Specimen TCGA-18-3417-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a899adcf-170f-49e3-b94f-53fcfcf6fcf7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-18-3417-11A (Solid Tissue Normal), aliquot TCGA-18-3417-11A-01D-1441-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/905dfe42-8d45-4d60-94ba-79211e2d977e

The open-access MAF lists 300 somatic variants for this specimen: 230 protein-altering or splice-affecting, 63 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 195, Silent 63, Nonsense Mutation 18, Frame Shift Del 8, Splice Site 5, Intron 5, Splice Region 4, RNA 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.375G>T p.T125= | Splice Region (SNP) | VAF 52/147 reads (35%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- AASDH | c.2167A>G p.N723D | Missense Mutation (SNP) | VAF 19/158 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV52710471; called by muse, mutect2, varscan2
- ABAT | c.793G>T p.E265* | Nonsense Mutation (SNP) | VAF 39/257 reads (15%) | catalogued as COSV51628024; called by muse, mutect2, varscan2
- ACAN | c.4233C>A p.S1411R | Missense Mutation (SNP) | VAF 62/208 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV61368841; called by muse, varscan2
- ACBD5 | c.746A>G p.Q249R (on ENST00000375888 / NM_001352568.1; = p.Q240R on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/332 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.159); catalogued as rs1258435246, COSV65521224; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACTC1 | c.868G>T p.D290Y | Missense Mutation (SNP) | VAF 39/350 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.992); catalogued as COSV51761350; called by muse, mutect2, varscan2
- ADCY8 | c.3475A>G p.S1159G | Missense Mutation (SNP) | VAF 20/285 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV53926223; called by muse, mutect2
- ADCY8 | c.1440C>A p.H480Q | Missense Mutation (SNP) | VAF 65/162 reads (40%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.95); catalogued as COSV53926232; called by muse, mutect2, varscan2
- ADGRL3 | c.2023C>T p.R675W (on ENST00000506720 / NM_001322402.2; = p.R607W on NM_015236.6) | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1047688064, COSV63368296; called by muse, mutect2, varscan2
- ALDH16A1 | c.1508A>G p.Y503C | Missense Mutation (SNP) | VAF 142/491 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.956); catalogued as rs898170516, COSV53196616, COSV99513179; called by muse, mutect2, varscan2
- AMBN | c.451G>C p.G151R | Missense Mutation (SNP) | VAF 63/218 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.019); catalogued as COSV59828080; called by muse, mutect2, varscan2
- AMELX | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs771933695, COSV61635437; called by muse, mutect2, varscan2
- ANKS1B | c.1351G>C p.E451Q | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.127); catalogued as COSV61374906; called by muse, mutect2, varscan2
- AP2A1 | c.1436C>G p.A479G | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV62819890, COSV62820909; called by muse, mutect2, varscan2
- AQP6 | c.623G>C p.G208A | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.836); catalogued as COSV59646907; called by muse, mutect2
- ARID4A | c.1673A>G p.K558R | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as COSV62166550; called by muse, mutect2, varscan2
- ARRDC3 | c.1217A>G p.D406G | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as COSV54365938; called by muse, mutect2, varscan2
- ARRDC4 | c.402A>T p.K134N | Missense Mutation (SNP) | VAF 13/229 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51420321; called by muse, mutect2
- ATCAY | c.502C>A p.L168M | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.041); catalogued as COSV56659107; called by muse, mutect2, varscan2
- ATM | c.5025G>T p.L1675F | Missense Mutation (SNP) | VAF 27/247 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53773506; called by muse, mutect2, varscan2
- BBS12 | c.1954A>T p.I652F | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.059); catalogued as COSV58563028; called by muse, mutect2, varscan2
- BCAR1 | c.2126A>T p.Q709L | Missense Mutation (SNP) | VAF 66/129 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV50802646; called by muse, mutect2, varscan2
- BCOR | c.1814C>A p.P605H | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as COSV60717930; called by muse, mutect2, varscan2
- BRINP3 | c.1854G>A p.W618* | Nonsense Mutation (SNP) | VAF 194/548 reads (35%) | catalogued as COSV66513576, COSV66524701; called by mutect2, varscan2
- C5orf34 | c.1898T>G p.L633R | Missense Mutation (SNP) | VAF 77/242 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60931967; called by muse, mutect2, varscan2
- C8B | c.395G>T p.R132M | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64779546; called by muse, mutect2
- CALML5 | c.298G>T p.V100L | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.547); catalogued as COSV66702736; called by muse, mutect2
- CCDC6 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54060291; called by muse, mutect2, varscan2
- CCT7 | c.1114T>C p.F372L | Missense Mutation (SNP) | VAF 111/282 reads (39%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs1006560783, COSV54589543; called by muse, mutect2, varscan2
- CDH10 | c.178C>T p.Q60* | Nonsense Mutation (SNP) | VAF 103/434 reads (24%) | catalogued as COSV52596680, COSV52599466; called by muse, mutect2, varscan2
- CEACAM4 | c.141G>T p.E47D | Missense Mutation (SNP) | VAF 62/217 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55731565; called by muse, mutect2, varscan2
- CEP135 | c.1401A>G p.I467M | Missense Mutation (SNP) | VAF 65/228 reads (29%) | SIFT tolerated (0.92); PolyPhen benign (0.012); catalogued as COSV57262669; called by muse, mutect2, varscan2
- CEP97 | c.1893G>T p.Q631H | Missense Mutation (SNP) | VAF 58/199 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.117); catalogued as COSV59127920; called by muse, mutect2, varscan2
- CER1 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.022); catalogued as rs748038785, COSV66603872; called by muse, mutect2, varscan2
- CFAP47 | c.5523C>G p.D1841E | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as COSV57974744, COSV57976529; called by muse, mutect2, varscan2
- CGB5 | c.481C>A p.P161T | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); catalogued as rs1298182227, COSV100032074; called by muse, mutect2, varscan2
- CHEK1 | c.1257G>T p.R419S | Missense Mutation (SNP) | VAF 28/200 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.184); catalogued as COSV54022186; called by muse, mutect2, varscan2
- CHFR | c.874G>T p.A292S (on ENST00000432561 / NM_001161345.1; = p.A251S on NM_018223.2) | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs1341883561, COSV57177801; called by muse, mutect2, varscan2
- CNGB3 | c.1148C>A p.T383N | Missense Mutation (SNP) | VAF 44/313 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.587); catalogued as CD001927, COSV60697975, COSV60699748; called by muse, mutect2, varscan2
- COL4A1 | c.4810T>A p.C1604S | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV65431785; called by muse, mutect2, varscan2
- COPG1 | c.1831G>T p.E611* | Nonsense Mutation (SNP) | VAF 51/199 reads (26%) | catalogued as COSV59116432; called by muse, mutect2, varscan2
- CPT1C | c.814G>T p.A272S | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); catalogued as COSV54919597, COSV54922054; called by muse, mutect2, varscan2
- CSMD1 | c.9350G>T p.G3117V (on ENST00000520002; = p.G3116V on NM_033225.6) | Missense Mutation (SNP) | VAF 61/233 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59380275; called by muse, mutect2, varscan2
- CSMD3 | c.3191A>T p.D1064V (on ENST00000297405 / NM_001363185.1; = p.D960V on NM_052900.3) | Missense Mutation (SNP) | VAF 82/185 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV52310905; called by muse, mutect2, varscan2
- CTSW | c.286+2T>G p.X96_splice | Splice Site (SNP) | VAF 143/1049 reads (14%) | catalogued as COSV57173162; called by muse, mutect2, varscan2
- CTTNBP2NL | c.1255G>A p.A419T | Missense Mutation (SNP) | VAF 167/480 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.588); catalogued as COSV54744071, COSV54746804; called by muse, mutect2, varscan2
- CWF19L2 | c.625C>G p.L209V | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56519880; called by muse, mutect2
- CYP26A1 | c.491T>C p.L164P | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56419908; called by muse, mutect2, varscan2
- DACH1 | c.932G>T p.G311V | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.889); catalogued as COSV100498796; called by muse, varscan2
- DCC | c.338G>T p.G113V | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59133096, COSV59141256; called by muse, mutect2, varscan2
- DCLK3 | c.1544G>C p.G515A | Missense Mutation (SNP) | VAF 70/313 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV69364675; called by muse, mutect2, varscan2
- DDIT4 | c.223G>C p.G75R | Missense Mutation (SNP) | VAF 98/272 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0.082); catalogued as COSV56578138; called by muse, mutect2, varscan2
- DHX9 | c.593A>G p.Y198C | Missense Mutation (SNP) | VAF 100/238 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62362097; called by muse, mutect2, varscan2
- DIP2A | c.2658G>T p.Q886H | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.896); catalogued as rs759036409, COSV59485217; called by muse, mutect2, varscan2
- DNAH5 | c.1012A>G p.T338A | Missense Mutation (SNP) | VAF 20/229 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54225883; called by muse, mutect2
- DNAH8 | c.10697C>T p.P3566L | Missense Mutation (SNP) | VAF 14/282 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59478753; called by muse, mutect2
- DRC1 | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56535302; called by muse, mutect2, varscan2
- EIF3E | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 75/167 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0.164); catalogued as COSV55205826; called by muse, mutect2, varscan2
- ELP4 | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs768226773, COSV53446533; called by muse, mutect2, varscan2
- EPB41L3 | c.1484C>T p.S495L | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.022); catalogued as rs769159490, COSV59461373; called by muse, mutect2, varscan2
- EPHA6 | c.1969G>A p.V657I (on ENST00000389672 / NM_001080448.3; = p.V49I on NM_173655.4) | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.031); catalogued as rs753848380, COSV67592998; called by mutect2, varscan2
- FAM169B | n.709G>A | Splice Region (SNP) | VAF 24/76 reads (32%) | catalogued as COSV60570388; called by muse, mutect2, varscan2
- FAM234B | c.658G>C p.A220P | Missense Mutation (SNP) | VAF 11/157 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.042); catalogued as COSV52197380; called by muse, mutect2
- FAM47C | c.2104C>T p.L702F | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.144); catalogued as COSV63730206; called by muse, mutect2, varscan2
- FBXO11 | c.1096A>T p.I366F (on ENST00000403359 / NM_001190274.2; = p.I282F on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/395 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.855); catalogued as COSV57025972; called by muse, mutect2, varscan2
- FBXO30 | c.1378A>G p.T460A | Missense Mutation (SNP) | VAF 57/344 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52792298; called by muse, mutect2, varscan2
- FCGR2A | c.902A>T p.K301I (on ENST00000271450 / NM_001136219.3; = p.K300I on NM_021642.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/919 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.248); catalogued as COSV54840582; called by muse, mutect2
- FGFR4 | c.430C>G p.Q144E | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52809611; called by muse, mutect2, varscan2
- FMN2 | c.1318A>T p.S440C | Missense Mutation (SNP) | VAF 50/128 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV60452461; called by muse, mutect2, varscan2
- FOLH1 | c.2104G>A p.G702R | Missense Mutation (SNP) | VAF 19/209 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV57049272; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.136C>G p.R46G | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV63049672; called by muse, mutect2, varscan2
- G2E3 | c.221A>G p.N74S | Missense Mutation (SNP) | VAF 43/232 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as rs1331722497, COSV52842769; called by muse, mutect2, varscan2
- GCN1 | c.166T>G p.L56V | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.281); catalogued as COSV56114497; called by muse, mutect2
- GET4 | c.235C>T p.Q79* | Nonsense Mutation (SNP) | VAF 26/255 reads (10%) | catalogued as COSV56254424; called by muse, mutect2, varscan2
- GIMAP2 | c.86G>A p.G29D | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56236284; called by muse, mutect2, varscan2
- GNPAT | c.1196C>T p.S399F | Missense Mutation (SNP) | VAF 91/174 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as COSV64154319; called by muse, mutect2, varscan2
- GPR158 | c.1514G>C p.R505T | Missense Mutation (SNP) | VAF 39/269 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66269630, COSV66281948; called by muse, mutect2, varscan2
- GPR27 | c.803G>T p.R268L | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs1019921991, COSV55206917, COSV55207540; called by muse, mutect2, varscan2
- GRIA1 | c.532T>A p.L178M | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV53623565; called by muse, mutect2, varscan2
- GRID2 | c.1459G>C p.E487Q | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.469); catalogued as COSV56174151, COSV56263047; called by muse, mutect2, varscan2
- GRM3 | c.985C>A p.P329T | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT tolerated (0.42); PolyPhen benign (0.022); catalogued as rs765170035, COSV64479201; called by muse, mutect2, varscan2
- GRM7 | c.2471C>T p.T824M | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs760785925, COSV100735969, COSV63169543; called by muse, mutect2, varscan2
- HNRNPUL1 | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 61/235 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54561436; called by muse, mutect2, varscan2
- HNRNPUL2 | c.1059G>C p.Q353H | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as COSV57132751, COSV57133762; called by muse, mutect2, varscan2
- HOXA3 | c.838A>T p.M280L | Missense Mutation (SNP) | VAF 85/145 reads (59%) | SIFT tolerated (0.87); PolyPhen possibly damaging (0.518); catalogued as COSV57828830; called by muse, mutect2, varscan2
- IFT140 | c.362G>T p.G121V | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs375698323; called by muse, mutect2, varscan2
- IGF2BP2 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 45/319 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as COSV60491064; called by muse, mutect2, varscan2
- IGSF1 | c.556del p.I186Lfs*4 | Frame Shift Del (DEL) | VAF 44/121 reads (36%) | catalogued as COSV100812088; called by mutect2, pindel, varscan2
- IL5RA | c.346G>T p.A116S | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV56526531, COSV99843065; called by muse, mutect2, varscan2
- ITIH1 | c.1963T>A p.S655T | Missense Mutation (SNP) | VAF 53/293 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.026); catalogued as COSV56258357; called by muse, mutect2, varscan2
- ITPR2 | c.6274G>C p.D2092H | Missense Mutation (SNP) | VAF 13/197 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.224); catalogued as COSV67275827; called by muse, mutect2
- KAT8 | c.322C>T p.R108W | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54898817; called by muse, mutect2, varscan2
- KCNH6 | c.2419A>T p.S807C | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.497); catalogued as COSV59007402; called by muse, mutect2, varscan2
- KCNN4 | c.244A>G p.K82E | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.393); catalogued as COSV53457195; called by muse, mutect2, varscan2
- KDM5D | c.550G>T p.E184* | Nonsense Mutation (SNP) | VAF 11/27 reads (41%) | catalogued as COSV58737236; called by muse, mutect2, varscan2
- KDR | c.1586A>T p.K529I | Missense Mutation (SNP) | VAF 59/448 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV55775635; called by muse, mutect2, varscan2
- KIF5C | c.1970T>A p.L657Q | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV68483749; called by muse, mutect2, varscan2
- KMT2C | c.595C>T p.R199* | Nonsense Mutation (SNP) | VAF 46/203 reads (23%) | catalogued as COSV51443293; called by muse, mutect2, varscan2
- KTI12 | c.709G>T p.E237* | Nonsense Mutation (SNP) | VAF 43/138 reads (31%) | catalogued as COSV65406105; called by muse, mutect2, varscan2
- LEPR | c.3265G>T p.E1089* | Nonsense Mutation (SNP) | VAF 39/129 reads (30%) | catalogued as COSV62751615; called by muse, mutect2, varscan2
- LPP | c.396G>C p.E132D | Missense Mutation (SNP) | VAF 16/383 reads (4%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.971); catalogued as COSV57113915; called by muse, mutect2
- LRP1B | c.3775G>A p.E1259K | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (1); PolyPhen possibly damaging (0.824); catalogued as COSV67252475, COSV67266690; called by muse, mutect2, varscan2
- LUZP1 | c.1484G>T p.G495V | Missense Mutation (SNP) | VAF 40/337 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0.155); catalogued as COSV56505150; called by muse, mutect2, varscan2
- LVRN | c.248C>A p.T83N | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.027); catalogued as COSV63498327; called by muse, mutect2, varscan2
- MCCC1 | c.842G>T p.R281L | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1110114, COSV55611696; called by muse, varscan2
- MCCC1 | c.762G>T p.R254S | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55611702; called by muse, varscan2
- MCCC1 | c.762-1G>T p.X254_splice | Splice Site (SNP) | VAF 11/52 reads (21%) | catalogued as CS110414, COSV55611711; called by muse, varscan2
- MCM3AP | c.568G>T p.A190S | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.014); catalogued as COSV52445386; called by muse, mutect2, varscan2
- MDM1 | c.1502C>G p.S501* | Nonsense Mutation (SNP) | VAF 47/118 reads (40%) | catalogued as COSV57447306, COSV57448786; called by muse, mutect2, varscan2
- MEGF9 | c.1745G>A p.G582D | Missense Mutation (SNP) | VAF 61/212 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as COSV64237666; called by muse, mutect2, varscan2
- MEGF9 | c.1744G>C p.G582R | Missense Mutation (SNP) | VAF 61/217 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as COSV64237675; called by muse, mutect2, varscan2
- MLLT1 | c.419G>T p.G140V | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV53133260; called by muse, varscan2
- MMP16 | c.671C>A p.S224* | Nonsense Mutation (SNP) | VAF 70/170 reads (41%) | catalogued as COSV54188188; called by muse, mutect2, varscan2
- MMP8 | c.457C>A p.Q153K | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV52634258; called by muse, mutect2, varscan2
- MMRN1 | c.641T>A p.V214E | Missense Mutation (SNP) | VAF 53/194 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53342322; called by muse, mutect2, varscan2
- MRGPRD | c.350C>T p.T117M | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.876); catalogued as rs147515740, COSV100483105; called by muse, mutect2, varscan2
- MS4A10 | c.76C>T p.Q26* | Nonsense Mutation (SNP) | VAF 26/162 reads (16%) | catalogued as COSV57632582; called by muse, mutect2, varscan2
- MYOF | c.2474del p.N825Tfs*12 | Frame Shift Del (DEL) | VAF 13/81 reads (16%) | catalogued as rs776353584; called by mutect2, pindel, varscan2
- MYT1L | c.3155G>A p.R1052Q | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.036); catalogued as rs749557195, COSV67704791; called by muse, mutect2
- NARS1 | c.569A>C p.K190T | Missense Mutation (SNP) | VAF 28/202 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as COSV56878151; called by muse, mutect2, varscan2
- NEB | c.5629A>T p.S1877C | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51458702; called by muse, mutect2
- NINL | c.998A>T p.Q333L | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54008604; called by muse, mutect2, varscan2
- NLRP14 | c.40G>T p.G14W | Missense Mutation (SNP) | VAF 27/223 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55072186; called by muse, mutect2, varscan2
- NPAS4 | c.863C>T p.T288I | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV60652736; called by muse, mutect2, varscan2
- NR3C2 | c.2215G>T p.V739F | Missense Mutation (SNP) | VAF 78/232 reads (34%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.569); catalogued as COSV60986618, COSV60999595; called by muse, mutect2, varscan2
- NRIP1 | c.2632G>T p.V878F | Missense Mutation (SNP) | VAF 69/311 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.165); catalogued as COSV59660179; called by muse, mutect2, varscan2
- NRROS | c.1440C>A p.C480* | Nonsense Mutation (SNP) | VAF 74/218 reads (34%) | catalogued as COSV60747712; called by muse, mutect2, varscan2
- NTAQ1 | c.172G>C p.E58Q | Missense Mutation (SNP) | VAF 47/367 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.283); catalogued as COSV54876076; called by muse, mutect2, varscan2
- OR2D3 | c.884C>A p.T295K | Missense Mutation (SNP) | VAF 16/165 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs1329886629, COSV53494847; called by muse, mutect2, varscan2
- OR4K1 | c.695G>T p.G232V | Missense Mutation (SNP) | VAF 31/250 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs778635980, COSV53462401; called by muse, mutect2, varscan2
- OR4N2 | c.574A>G p.T192A | Missense Mutation (SNP) | VAF 28/392 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as COSV60054746; called by muse, mutect2
- OR51L1 | c.225G>T p.M75I | Missense Mutation (SNP) | VAF 27/182 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.023); catalogued as COSV58625708; called by muse, mutect2, varscan2
- OR5D13 | c.731C>T p.A244V | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs76632744, COSV62333002; called by muse, mutect2, varscan2
- OR5D18 | c.722C>A p.T241N | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61737767; called by muse, mutect2
- OR5P2 | c.164T>C p.M55T | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as rs1396472764, COSV61490554; called by muse, mutect2, varscan2
- OR6C75 | c.338T>C p.L113P | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV58553478; called by muse, mutect2, varscan2
- OR8K1 | c.29C>A p.T10K | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as COSV54401974; called by muse, mutect2, varscan2
- OR8K5 | c.200C>A p.A67D | Missense Mutation (SNP) | VAF 15/161 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV57891109; called by muse, mutect2
- OSBPL2 | c.157C>T p.Q53* (on ENST00000313733 / NM_144498.4; = p.Q41* on NM_014835.4) | Nonsense Mutation (SNP) | VAF 22/181 reads (12%) | catalogued as COSV58215239, COSV58219785; called by muse, mutect2, varscan2
- PARD3B | c.2015A>T p.Y672F | Missense Mutation (SNP) | VAF 68/157 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV62529795; called by muse, mutect2, varscan2
- PBRM1 | c.2966-1G>A p.X989_splice | Splice Site (SNP) | VAF 66/124 reads (53%) | catalogued as COSV56270893, COSV56302997; called by muse, mutect2
- PBRM1 | c.676G>C p.E226Q | Missense Mutation (SNP) | VAF 117/231 reads (51%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.832); catalogued as COSV56303013; called by muse, mutect2, varscan2
- PCDHGB4 | c.449C>T p.T150I | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.214); catalogued as COSV54027152; called by muse, mutect2, varscan2
- PCLO | c.2743G>T p.A915S | Missense Mutation (SNP) | VAF 122/230 reads (53%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as rs574502381, COSV61664149; called by muse, mutect2, varscan2
- PDGFRB | c.411C>G p.I137M | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV55809866; called by muse, mutect2, varscan2
- PEPD | c.1309C>T p.R437C | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as rs376372688; ClinVar: uncertain significance; called by muse, mutect2
- PEX5L | c.1154+1G>A p.X385_splice | Splice Site (SNP) | VAF 136/307 reads (44%) | catalogued as COSV55856811; called by muse, mutect2, varscan2
- PHEX | c.1640A>T p.Q547L | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV65078729; called by muse, mutect2, varscan2
- PKD2L1 | c.278G>T p.R93L | Missense Mutation (SNP) | VAF 54/164 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV58398710; called by muse, mutect2, varscan2
- PKHD1 | c.8821G>A p.G2941S | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.631); catalogued as rs1427843169, COSV61893885; called by muse, mutect2, varscan2
- PLAGL2 | c.716A>G p.K239R | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV55789398; called by muse, mutect2, varscan2
- PLPBP | c.212A>C p.Q71P | Missense Mutation (SNP) | VAF 91/447 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.748); catalogued as COSV60240357; called by muse, mutect2, varscan2
- PLXND1 | c.4235T>C p.L1412S | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60719257; called by muse, mutect2, varscan2
- PNRC1 | c.795G>T p.K265N | Missense Mutation (SNP) | VAF 36/202 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV60140492; called by muse, mutect2, varscan2
- POLQ | c.2899A>G p.S967G | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.053); catalogued as COSV51760855; called by muse, mutect2, varscan2
- PPEF2 | c.577A>G p.K193E | Missense Mutation (SNP) | VAF 9/159 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV54426085; called by muse, mutect2
- PRKAR1A | c.428A>T p.D143V | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.243); catalogued as COSV62236516; called by muse, mutect2, varscan2
- PRKCG | c.980C>A p.P327H | Missense Mutation (SNP) | VAF 43/146 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.227); catalogued as COSV54732589; called by muse, mutect2, varscan2
- PRLR | c.1471C>T p.P491S | Missense Mutation (SNP) | VAF 102/379 reads (27%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs1206108227, COSV51492933; called by muse, mutect2, varscan2
- PTEN | c.382A>C p.K128Q | Missense Mutation (SNP) | VAF 83/216 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as HM090026, COSV64292814, COSV64297304; called by muse, mutect2, varscan2
- PTPRO | c.3476A>C p.H1159P (on ENST00000281171 / NM_030667.3; = p.H1131P on NM_002848.4) | Missense Mutation (SNP) | VAF 96/476 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55522357; called by muse, mutect2, varscan2
- PTPRT | c.1295A>T p.Q432L | Missense Mutation (SNP) | VAF 62/158 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV62017630; called by muse, mutect2, varscan2
- PWWP3B | c.44G>T p.W15L | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61801652; called by muse, mutect2
- RAB26 | c.489C>A p.H163Q | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.011); catalogued as COSV52955342; called by muse, mutect2
- RAI14 | c.2020G>A p.E674K | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.033); catalogued as COSV54303158; called by muse, mutect2, varscan2
- RGMA | c.742A>T p.K248* | Nonsense Mutation (SNP) | VAF 8/120 reads (7%) | catalogued as COSV61236734; called by muse, mutect2
- RIMS2 | c.3719G>T p.S1240I | Missense Mutation (SNP) | VAF 30/325 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV51721935; called by muse, mutect2
- RPUSD4 | c.794C>T p.T265I | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149309585; called by muse, mutect2, varscan2
- RRM2B | c.32G>C p.G11A | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.001); catalogued as COSV52568522; called by muse, mutect2, varscan2
- RSPH6A | c.885G>T p.E295D | Missense Mutation (SNP) | VAF 122/418 reads (29%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as COSV55574539; called by muse, mutect2, varscan2
- RYR3 | c.7792G>A p.D2598N (on ENST00000389232; = p.D2599N on NM_001036.6) | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.029); catalogued as COSV66807674; called by muse, mutect2, varscan2
- SCN3B | c.169A>T p.T57S | Missense Mutation (SNP) | VAF 33/182 reads (18%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV54801209; called by muse, mutect2, varscan2
- SCUBE3 | c.672T>A p.H224Q | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV51460422; called by muse, mutect2, varscan2
- SEL1L2 | c.663G>A p.L221= | Splice Region (SNP) | VAF 35/169 reads (21%) | catalogued as COSV53157962; called by muse, mutect2, varscan2
- SEMA3F | c.46G>T p.A16S | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.124); catalogued as COSV50035728; called by muse, mutect2, varscan2
- SETD1A | c.2866C>T p.R956C | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.482); catalogued as rs150435865; called by muse, mutect2, varscan2
- SEZ6L | c.1010T>C p.I337T | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50685335; called by muse, mutect2, varscan2
- SLC2A13 | c.1197A>G p.A399= | Splice Region (SNP) | VAF 23/117 reads (20%) | catalogued as COSV55127992; called by muse, mutect2, varscan2
- SLC4A4 | c.2737G>A p.G913R (on ENST00000264485 / NM_001098484.3; = p.G869R on NM_003759.4) | Missense Mutation (SNP) | VAF 101/405 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52637517; called by muse, mutect2, varscan2
- SLC8A1 | c.1294A>T p.R432* | Nonsense Mutation (SNP) | VAF 72/198 reads (36%) | catalogued as COSV60495633; called by muse, mutect2, varscan2
- SLCO1B1 | c.248T>G p.F83C | Missense Mutation (SNP) | VAF 27/201 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57016519; called by muse, mutect2, varscan2
- SPAST | c.1250G>C p.G417A | Missense Mutation (SNP) | VAF 93/274 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as CM090379, COSV59517520; called by muse, mutect2, varscan2
- SQLE | c.32C>A p.T11N | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.917); catalogued as COSV56282555; called by muse, mutect2, varscan2
- SRCAP | c.3493G>A p.A1165T | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1437948134, COSV52680470; called by muse, mutect2, varscan2
- STAC | c.294G>T p.R98S | Missense Mutation (SNP) | VAF 110/247 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.36); catalogued as COSV56207140; called by muse, mutect2, varscan2
- SYNE1 | c.12078+1G>T p.X4026_splice (on ENST00000367255 / NM_182961.4; = p.X3955_splice on NM_033071.3) | Splice Site (SNP) | VAF 20/104 reads (19%) | catalogued as COSV55095538; called by muse, mutect2, varscan2
- SYNE1 | c.5230G>A p.E1744K (on ENST00000367255 / NM_182961.4; = p.E1751K on NM_033071.3) | Missense Mutation (SNP) | VAF 51/237 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.227); catalogued as rs540091060, COSV54903395; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYNE1 | c.4054G>T p.V1352L (on ENST00000367255 / NM_182961.4; = p.V1359L on NM_033071.3) | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as COSV55095621; called by muse, mutect2, varscan2
- TAB1 | c.1298C>T p.T433I | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.368); catalogued as rs1387025284, COSV53370937; called by muse, mutect2, varscan2
- TAFA1 | c.141A>G p.I47M | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV72041010; called by muse, mutect2, varscan2
- TAS2R4 | c.250T>C p.F84L | Missense Mutation (SNP) | VAF 128/381 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.198); catalogued as COSV56094127; called by muse, mutect2, varscan2
- TENM3 | c.7772G>T p.R2591L | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as COSV101304934; called by mutect2, varscan2
- THSD4 | c.1432G>T p.G478* | Nonsense Mutation (SNP) | VAF 29/272 reads (11%) | catalogued as COSV55983779, COSV99966606; called by muse, mutect2, varscan2
- THSD4 | c.1433G>A p.G478E | Missense Mutation (SNP) | VAF 30/274 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV55978703, COSV55983785; called by muse, mutect2, varscan2
- TMEM102 | c.18G>T p.W6C | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV53441143; called by muse, mutect2, varscan2
- TMEM132E | c.1058C>T p.P353L (on ENST00000321639; = p.P443L on NM_001304438.2) | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV58694395, COSV58700406; called by muse, mutect2, varscan2
- TMEM209 | c.1418C>A p.T473N | Missense Mutation (SNP) | VAF 188/396 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV61023620; called by muse, mutect2, varscan2
- TNN | c.2780G>T p.R927M | Missense Mutation (SNP) | VAF 68/165 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.232); catalogued as COSV53422248; called by muse, mutect2, varscan2
- TRHDE | c.1775C>G p.T592R | Missense Mutation (SNP) | VAF 104/245 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV53864927; called by muse, mutect2, varscan2
- TRIM4 | c.1147G>C p.E383Q | Missense Mutation (SNP) | VAF 61/300 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62470340; called by muse, mutect2, varscan2
- TRIM51 | c.842G>A p.S281N | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV55270764; called by muse, mutect2, varscan2
- TTC39A | c.695T>A p.L232Q (on ENST00000447632 / NM_001297665.1; = p.L197Q on NM_001080494.3) | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52961429; called by muse, mutect2, varscan2
- TYK2 | c.959G>T p.G320V | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53391862; called by muse, mutect2, varscan2
- UBE2L6 | c.372C>A p.D124E | Missense Mutation (SNP) | VAF 41/346 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV54703891; called by muse, mutect2, varscan2
- USP25 | c.2614A>T p.R872W | Missense Mutation (SNP) | VAF 53/234 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV53490200; called by muse, mutect2, varscan2
- USP47 | c.3215T>G p.F1072C (on ENST00000399455 / NM_001372095.1; = p.F984C on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/225 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.62); catalogued as COSV59694684; called by muse, mutect2, varscan2
- VNN1 | c.1153G>C p.G385R | Missense Mutation (SNP) | VAF 37/246 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV100907719, COSV63390840, COSV63391001; called by muse, mutect2, varscan2
- VPS13B | c.9278C>T p.S3093F | Missense Mutation (SNP) | VAF 19/509 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62156206; called by muse, mutect2
- VPS35L | c.132G>C p.K44N | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV51991128; called by muse, mutect2, varscan2
- WDR17 | c.2953G>A p.E985K | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as COSV54583537; called by muse, mutect2, varscan2
- YIPF1 | c.317G>T p.G106V | Missense Mutation (SNP) | VAF 71/292 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV50779599; called by muse, mutect2, varscan2
- ZBTB20 | c.1855G>C p.D619H (on ENST00000474710 / NM_001164342.2; = p.D546H on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/173 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.323); catalogued as COSV61867749; called by muse, mutect2, varscan2
- ZGPAT | c.179G>C p.S60T | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV60833351; called by muse, mutect2, varscan2
- ZGRF1 | c.1258A>T p.S420C | Missense Mutation (SNP) | VAF 31/230 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.847); catalogued as COSV52203177; called by muse, mutect2, varscan2
- ZKSCAN3 | c.221G>T p.W74L | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52854336; called by muse, mutect2, varscan2
- ZNF229 | c.324C>G p.I108M | Missense Mutation (SNP) | VAF 42/186 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.238); catalogued as COSV52160679, COSV52164768; called by muse, mutect2, varscan2
- ZNF282 | c.1070C>G p.S357C | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.85); catalogued as COSV50483538; called by muse, mutect2, varscan2
- ZNF320 | c.190G>A p.G64S | Missense Mutation (SNP) | VAF 112/393 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV67088911; called by muse, mutect2, varscan2
- ZNF358 | c.1166G>T p.S389I | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV51181383; called by muse, mutect2
- ZNF462 | c.1046A>C p.K349T | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.549); catalogued as COSV52950423; called by muse, mutect2, varscan2
- ZNF804B | c.3378C>A p.D1126E | Missense Mutation (SNP) | VAF 95/202 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.549); catalogued as COSV60853641; called by muse, mutect2, varscan2
- B3GALT4 | c.369_370del p.Q124Gfs*3 | Frame Shift Del (DEL) | VAF 16/179 reads (9%) | called by mutect2, pindel
- DUSP19 | c.266del p.K89Rfs*4 | Frame Shift Del (DEL) | VAF 24/160 reads (15%) | called by mutect2, pindel, varscan2
- FRG2C | c.47A>G p.Q16R | Missense Mutation (SNP) | VAF 46/209 reads (22%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNH8 | c.2013_2035del p.Y671* | Frame Shift Del (DEL) | VAF 18/73 reads (25%) | called by mutect2, pindel
- MUC16 | c.8415del p.T2806Lfs*14 | Frame Shift Del (DEL) | VAF 6/36 reads (17%) | called by mutect2, pindel
- SLC12A6 | c.799_812del p.A267Lfs*18 (on ENST00000354181 / NM_001365088.1; = p.A216Lfs*18 on NM_005135.2) | Frame Shift Del (DEL) | VAF 58/207 reads (28%) | called by mutect2, pindel, varscan2
- TUBGCP5 | c.2719C>T p.H907Y | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- ZNF528 | c.992del p.G331Afs*10 | Frame Shift Del (DEL) | VAF 39/140 reads (28%) | called by mutect2, pindel, varscan2
- ZNF676 | c.1443C>A p.Y481* (on ENST00000650058; = p.Y449* on NM_001001411.3) | Nonsense Mutation (SNP) | VAF 35/224 reads (16%) | called by muse, mutect2, varscan2
- ABCA3 | c.2223G>T p.L741= | Silent (SNP) | VAF 33/99 reads (33%) | catalogued as COSV57059620; called by muse, mutect2, varscan2
- ACTL7B | c.834C>T p.R278= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as rs948419126, COSV65927143; called by muse, mutect2, varscan2
- ANO2 | c.1272G>C p.G424= (on ENST00000356134 / NM_001278597.3; = p.G428= on NM_001278596.3) | Silent (SNP) | VAF 131/208 reads (63%) | catalogued as COSV59042148; called by muse, mutect2, varscan2
- ATP1A4 | c.1902C>A p.A634= | Silent (SNP) | VAF 92/347 reads (27%) | catalogued as COSV63628443; called by muse, mutect2, varscan2
- B3GALT6 | c.462G>A p.K154= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs1188654312, COSV55421448; called by muse, mutect2, varscan2
- CADM4 | c.1137A>G p.G379= | Silent (SNP) | VAF 78/348 reads (22%) | catalogued as COSV55929864; called by muse, varscan2
- CAMK1 | c.531C>G p.T177= | Silent (SNP) | VAF 31/110 reads (28%) | catalogued as COSV56540421; called by muse, mutect2, varscan2
- CD19 | c.1389C>T p.N463= | Silent (SNP) | VAF 20/133 reads (15%) | catalogued as rs201434626; called by muse, mutect2, varscan2
- CHD4 | c.1782G>A p.E594= (on ENST00000357008 / NM_001363606.2; = p.E607= on NM_001273.5) | Silent (SNP) | VAF 73/618 reads (12%) | catalogued as COSV58910431; called by muse, mutect2, varscan2
- CLSPN | c.3201C>T p.S1067= | Silent (SNP) | VAF 16/257 reads (6%) | catalogued as rs201356504, COSV52056908; called by muse, mutect2
- COL19A1 | c.1260A>G p.P420= | Silent (SNP) | VAF 37/206 reads (18%) | catalogued as rs1214831383, COSV59587378; called by muse, mutect2, varscan2
- CSK | c.330C>T p.T110= | Silent (SNP) | VAF 16/89 reads (18%) | catalogued as COSV54975838; called by muse, mutect2, varscan2
- CYP20A1 | c.534G>A p.Q178= | Silent (SNP) | VAF 127/278 reads (46%) | catalogued as COSV100619094, COSV61909813; called by muse, mutect2, varscan2
- DDX24 | c.456A>T p.P152= | Silent (SNP) | VAF 34/204 reads (17%) | catalogued as COSV58212369, COSV58213803; called by muse, mutect2, varscan2
- DEFB136 | c.51T>C p.P17= | Silent (SNP) | VAF 44/289 reads (15%) | catalogued as COSV66364075; called by muse, mutect2, varscan2
- DIPK2A | c.243C>A p.R81= | Silent (SNP) | VAF 30/121 reads (25%) | catalogued as COSV59858421; called by muse, mutect2, varscan2
- DLC1 | c.2268C>A p.P756= (on ENST00000276297 / NM_001348081.2; = p.P319= on NM_006094.5) | Silent (SNP) | VAF 8/85 reads (9%) | catalogued as COSV52326841; called by muse, varscan2
- DRAXIN | c.51G>T p.L17= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV53845235; called by muse, mutect2, varscan2
- FAM171A1 | c.510G>T p.T170= | Silent (SNP) | VAF 10/83 reads (12%) | catalogued as COSV65319906; called by muse, mutect2, varscan2
- FANCL | c.501G>T p.V167= | Silent (SNP) | VAF 36/97 reads (37%) | catalogued as COSV52077834; called by muse, mutect2, varscan2
- FN1 | c.3087G>A p.L1029= | Silent (SNP) | VAF 38/193 reads (20%) | catalogued as COSV60563736; called by muse, mutect2, varscan2
- FRY | c.1092G>T p.L364= | Silent (SNP) | VAF 16/128 reads (13%) | catalogued as COSV66579836; called by muse, varscan2
- GDE1 | c.621A>G p.P207= | Silent (SNP) | VAF 50/207 reads (24%) | catalogued as COSV62059882; called by muse, mutect2, varscan2
- GH2 | c.303G>T p.L101= | Silent (SNP) | VAF 58/132 reads (44%) | catalogued as rs777138043, COSV60427780; called by muse, mutect2, varscan2
- GIMAP6 | c.825C>A p.I275= | Silent (SNP) | VAF 107/204 reads (52%) | catalogued as COSV61033057, COSV61034722; called by muse, mutect2, varscan2
- IGHG2 | c.417G>A p.T139= | Silent (SNP) | VAF 31/104 reads (30%) | catalogued as rs368077478; called by muse, mutect2, varscan2
- IGHV3-13 | c.312G>T p.L104= | Silent (SNP) | VAF 63/217 reads (29%) | called by muse, mutect2, varscan2
- IGKV1-16 | c.33G>C p.G11= | Silent (SNP) | VAF 30/310 reads (10%) | catalogued as rs552338386; called by muse, varscan2
- IGKV3-7 | c.84A>T p.P28= | Silent (SNP) | VAF 83/243 reads (34%) | called by muse, mutect2, varscan2
- ITGA8 | c.2754T>G p.P918= | Silent (SNP) | VAF 33/225 reads (15%) | catalogued as rs746700510, COSV65235546; called by muse, mutect2, varscan2
- KIAA0586 | c.846C>T p.S282= (on ENST00000619416 / NM_001244190.2; = p.S297= on NM_014749.5) | Silent (SNP) | VAF 38/143 reads (27%) | catalogued as rs1424135868, COSV54182273; called by muse, mutect2, varscan2
- KRT6A | c.1131C>A p.T377= | Silent (SNP) | VAF 50/139 reads (36%) | catalogued as rs374230378, COSV100417090; called by muse, mutect2, varscan2
- KRT6B | c.1392C>A p.T464= | Silent (SNP) | VAF 83/220 reads (38%) | catalogued as rs763339267, COSV52886486, COSV99361103; called by muse, mutect2, varscan2
- KRTAP13-4 | c.312G>T p.S104= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as rs150222104, COSV61880274; called by muse, mutect2, varscan2
- LRFN5 | c.1818C>A p.T606= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as COSV53274079; called by muse, mutect2, varscan2
- MAGEB16 | c.282T>C p.D94= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs899497883, COSV67874539; called by muse, mutect2
- MCM3AP | c.567G>T p.L189= | Silent (SNP) | VAF 37/110 reads (34%) | catalogued as COSV52445394; called by muse, mutect2, varscan2
- MYH7 | c.2451C>T p.N817= | Silent (SNP) | VAF 39/154 reads (25%) | catalogued as COSV62523535; called by muse, mutect2, varscan2
- MYLK2 | c.1704C>T p.R568= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs771026828, COSV65659910; called by muse, mutect2, varscan2
- N4BP1 | c.420C>T p.L140= | Silent (SNP) | VAF 31/161 reads (19%) | catalogued as COSV52213227; called by muse, mutect2, varscan2
- NPHP3 | c.306C>T p.R102= | Silent (SNP) | VAF 17/115 reads (15%) | catalogued as rs762134618, COSV58130703; ClinVar: likely benign / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- OR52A5 | c.198C>A p.A66= | Silent (SNP) | VAF 16/100 reads (16%) | catalogued as COSV56616645; called by muse, mutect2, varscan2
- PCDH10 | c.153C>G p.R51= | Silent (SNP) | VAF 19/186 reads (10%) | catalogued as COSV52103498; called by muse, mutect2
- PCDHA10 | c.264G>T p.R88= | Silent (SNP) | VAF 92/304 reads (30%) | catalogued as COSV100251572, COSV56543369; called by muse, mutect2, varscan2
- PCSK2 | c.1350T>A p.G450= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as COSV52742805; called by muse, mutect2, varscan2
- PLEKHG2 | c.2892C>T p.L964= | Silent (SNP) | VAF 36/155 reads (23%) | catalogued as COSV52689727; called by muse, mutect2, varscan2
- PLEKHH2 | c.744C>T p.G248= | Silent (SNP) | VAF 28/182 reads (15%) | catalogued as COSV56760860; called by muse, mutect2, varscan2
- POLA2 | c.1407C>T p.F469= | Silent (SNP) | VAF 14/148 reads (9%) | catalogued as rs774071113, COSV55486096; called by muse, mutect2
- RPS4Y1 | c.144C>T p.L48= | Silent (SNP) | VAF 69/226 reads (31%) | catalogued as COSV51711232; called by muse, mutect2, varscan2
- RSU1 | c.630A>T p.V210= | Silent (SNP) | VAF 36/96 reads (38%) | catalogued as COSV61715930; called by muse, mutect2, varscan2
- SARAF | c.501G>T p.S167= | Silent (SNP) | VAF 14/128 reads (11%) | catalogued as rs190031427, COSV56358312; called by muse, mutect2, varscan2
- SERPINA4 | c.786C>A p.P262= | Silent (SNP) | VAF 12/95 reads (13%) | catalogued as COSV54071590; called by muse, mutect2, varscan2
- SLC10A2 | c.270T>C p.F90= | Silent (SNP) | VAF 20/178 reads (11%) | catalogued as COSV55361593; called by muse, mutect2
- SLC31A2 | c.342A>G p.V114= | Silent (SNP) | VAF 67/243 reads (28%) | catalogued as COSV52273572; called by muse, mutect2, varscan2
- SLC8A1 | c.2199A>G p.T733= | Silent (SNP) | VAF 72/183 reads (39%) | catalogued as COSV60495612; called by muse, mutect2, varscan2
- TCIRG1 | c.2346G>T p.V782= | Silent (SNP) | VAF 21/126 reads (17%) | catalogued as rs749090144, COSV55837410; called by muse, mutect2, varscan2
- TCTE1 | c.579C>T p.V193= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as COSV65256363; called by muse, mutect2
- TRIM38 | c.309C>T p.F103= | Silent (SNP) | VAF 25/96 reads (26%) | catalogued as COSV62642896; called by muse, mutect2, varscan2
- TRPC5 | c.1320T>C p.F440= | Silent (SNP) | VAF 38/102 reads (37%) | catalogued as COSV53302380; called by muse, mutect2, varscan2
- TSHZ3 | c.1791C>T p.S597= | Silent (SNP) | VAF 54/286 reads (19%) | catalogued as rs1040001659, COSV53682094; called by muse, mutect2, varscan2
- ZNF479 | c.1569T>C p.C523= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as rs1354757208, COSV58643372; called by muse, mutect2, varscan2
- ZNF536 | c.1971C>A p.R657= | Silent (SNP) | VAF 62/150 reads (41%) | catalogued as COSV62833606; called by muse, mutect2, varscan2
- ZNF790 | c.183A>G p.K61= | Silent (SNP) | VAF 22/107 reads (21%) | catalogued as COSV63213236; called by muse, mutect2, varscan2
- EEF1D | c.-7-2850A>G | Intron (SNP) | VAF 6/55 reads (11%) | catalogued as rs1351959249; called by muse, varscan2
- ERCC6 | c.1397+8151C>A | Intron (SNP) | VAF 49/219 reads (22%) | catalogued as COSV63394170; called by muse, mutect2, varscan2
- ERCC6 | c.1397+8150G>A | Intron (SNP) | VAF 47/218 reads (22%) | catalogued as COSV63394175; called by muse, mutect2, varscan2
- PCDHA8 | c.2394+48G>A | Intron (SNP) | VAF 22/81 reads (27%) | catalogued as rs782282230, COSV100969841; called by muse, mutect2, varscan2
- SNORD116-12 | n.63T>C | RNA (SNP) | VAF 13/166 reads (8%) | catalogued as rs767906416; called by muse, mutect2
- SSPOP | n.4355G>A | RNA (SNP) | VAF 13/51 reads (25%) | catalogued as rs767649508, COSV50489256; called by muse, mutect2, varscan2
- THSD4 | c.1016-70244G>C | Intron (SNP) | VAF 43/209 reads (21%) | catalogued as COSV55984840; called by muse, mutect2, varscan2
